HCMI case HCM-SANG-0271-D12 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/0a6a14db-ca5c-4bf9-9125-611d672bc67b

Demographics
Sex at birth: male; Days to birth: -16,618 days (45.5 years before the index date).

Diagnoses (1)
1. Tubular adenoma, NOS: ICD-O-3 morphology code: 8211/0; ICD-10 code: D12.5; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Sigmoid colon; Classification of tumor: Premalignant; Tumor grade: GX; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Uicc clinical stage: Stage I; Uicc pathologic m: M0; Uicc pathologic n: N0; Uicc pathologic stage: Stage 0; Uicc pathologic t: T0; Uicc staging system edition: 7th.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Days to comorbidity: 0 days; Days to risk factor: 0 days; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (9 samples)
- Sample HCM-SANG-0271-D12-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Premalignant.
- Sample HCM-SANG-0271-D12-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-SANG-0271-D12-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-SANG-0271-D12-31B: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples HCM-SANG-0271-D12-85A, HCM-SANG-0271-D12-85B (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Samples HCM-SANG-0271-D12-85A-01D-A80T-32, HCM-SANG-0271-D12-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid.
- Sample HCM-SANG-0271-D12-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
